Surgical pathology report (de-identified scan), TCGA case TCGA-CH-5761, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CH-5761-01A (Primary Tumor).

TCGA-CH-5761

Diagnosis

1. Poorly differentiated adenocarcinoma of the prostate in the left rectolateral and basal peripheral zone. Maximum tumor spread 2.6 cm. Extensive perineural infiltration and extraprostatic tumor growth in the left rectolateral and basal region. Infiltration of the left seminal vesicle. Infiltration of the surgical margins in the left rectolateral and basal resection.
2. Tumor-free fatty connective tissue with vessels and nerves
3. Fatty tissue with two tumor-free lymph nodes.
4. Fatty tissue with three tumor-free lymph nodes.

Remark

The tumor classification to date is as follows:

pT3b; Gleason 5+4 = 9 with small tertiary Gleason 3 portion (approx. 95% Gleason 5/4).

In the left lateral and basal region, carcinoma cells extend in a multifocal and elongated pattern the preparation margin (blue labeling, contact surface max. 8 mm and about 17 mm wide altogether).

To be on the safe side, additional immunohistological studies will follow to establish whether there is any invasion of the vessels and any lymph node metastases that could not yet be detected. The results will be presented in a follow-up report.

Follow-up report

Diagnosis already reported

Poorly differentiated adenocarcinoma of the prostate

Immunohistology (CD31) also showed no evidence for invasion of the vessels. In the submitted lymph nodes mentioned under 3. and 4., immunohistology also showed no metastases and no disseminated tumor cells.

Concluding tumor classification

pT3b, pN0 (0/3), L0, V0; Gleason 5+4=9.

At the request of the clinician, an additional immunohistological investigation will be carried out to settle the question of chromatin expression. The results will be presented in a follow-up report.

Source: NCI Genomic Data Commons file cde5d18a-0017-49ad-a30e-453c5aada3d5 (TCGA-CH-5761.205F9F59-486C-4211-AA60-0A5B4F746A74.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).